Somatic mutation profile of tumor specimen BA2524D (aliquot aq-BA2524D) from BEATAML1.0 case 2134, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, CBF-beta/MYH11; Tissue or organ of origin: Bone marrow; Age at diagnosis: 51.0 years (18,634 days).
Specimen BA2524D: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d2e5fce6-c2f5-4efd-a7b1-5f386a61edd7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2287D (Solid Tissue Normal), aliquot aq-BA2287D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/139b72b0-9011-4d6c-af82-87939246e7ac

The open-access MAF lists 17 somatic variants for this specimen: 11 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 7, Silent 6, Nonsense Mutation 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FLT3 | c.1715A>G p.Y572C | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs121913491, COSV54054678; ClinVar: likely pathogenic; called by mutect2, varscan2
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 6/24 reads (25%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- C16orf70 | c.59C>T p.T20M | Missense Mutation (SNP) | VAF 4/58 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.286); catalogued as rs889236423; called by muse, mutect2
- MCM7 | c.1378G>T p.E460* | Nonsense Mutation (SNP) | VAF 3/25 reads (12%) | catalogued as COSV57994377; called by muse, mutect2
- OR51V1 | c.820G>A p.V274M | Missense Mutation (SNP) | VAF 31/82 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.104); catalogued as rs182727082, COSV58314852; called by muse, mutect2, varscan2
- SRCAP | c.2833C>T p.R945* | Nonsense Mutation (SNP) | VAF 20/38 reads (53%) | catalogued as COSV52674752; called by muse, mutect2, varscan2
- AMFR | c.1069G>T p.G357* | Nonsense Mutation (SNP) | VAF 5/54 reads (9%) | called by muse, mutect2
- C18orf21 | c.59G>A p.G20D | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); called by muse, mutect2
- EFCC1 | c.616G>T p.E206* | Nonsense Mutation (SNP) | VAF 12/28 reads (43%) | called by muse, mutect2, varscan2
- GRIN2A | c.3359T>C p.I1120T | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.478); called by muse, mutect2, varscan2
- MESP2 | c.233C>A p.P78Q | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.028); called by muse, mutect2
- ARAF | c.1233G>A p.R411= | Silent (SNP) | VAF 5/36 reads (14%) | catalogued as rs1220609320, COSV51691410; called by muse, mutect2, varscan2
- DSG3 | c.2325C>T p.T775= | Silent (SNP) | VAF 18/44 reads (41%) | catalogued as COSV57125601; called by mutect2, varscan2
- NRAS | c.180A>G p.G60= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as COSV54752785, COSV99795904; called by muse, mutect2, varscan2
- PRSS56 | c.1635C>T p.A545= | Silent (SNP) | VAF 6/13 reads (46%) | called by muse, mutect2, varscan2
- ZDHHC5 | c.366C>A p.V122= | Silent (SNP) | VAF 3/12 reads (25%) | called by muse, varscan2
- ZNF804A | c.1872T>C p.N624= | Silent (SNP) | VAF 9/97 reads (9%) | called by muse, mutect2, varscan2
